Somatic mutation profile of tumor specimen TCGA-W5-AA2Q-01A (aliquot TCGA-W5-AA2Q-01A-11D-A417-09) from TCGA case TCGA-W5-AA2Q, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.6 years (25,069 days).
Specimen TCGA-W5-AA2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64fcf074-5c6e-4607-90d1-dc45d3ee3688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2Q-10A (Blood Derived Normal), aliquot TCGA-W5-AA2Q-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1fdace8-fae2-4514-950b-fe18052b87fb

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC5 | c.327dup p.A110Rfs*9 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs1351158680; called by mutect2, pindel, varscan2
- ATR | c.7880C>T p.A2627V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279843589; called by muse, mutect2, varscan2
- FZD8 | c.1313C>G p.S438W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157530595; called by muse, mutect2, varscan2
- HLA-DRA | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs751526731, COSV66622761; called by mutect2, varscan2
- KDR | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190064889, COSV55776975; called by muse, mutect2, varscan2
- LAMA3 | c.4264G>C p.G1422R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58062343; called by muse, mutect2
- LRRC6 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51543184, COSV99137759; called by muse, mutect2, varscan2
- MUC16 | c.18821del p.R6274Lfs*6 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as COSV67497597; called by mutect2, pindel, varscan2
- PFKP | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs755208226, COSV66901131; called by muse, mutect2, varscan2
- TRAF3IP2 | c.518del p.P173Lfs*32 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV60676639; called by mutect2, pindel, varscan2
- UBQLNL | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs765639960; called by muse, mutect2, varscan2
- ACSL3 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC9 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- C3 | c.4753A>G p.I1585V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CEP126 | c.3178T>C p.C1060R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GLG1 | c.2164A>T p.I722L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, varscan2
- LRIT3 | c.681T>A p.D227E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NELL2 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NR1I3 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP6C | c.614G>A p.W205* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- RDH12 | c.733T>A p.C245S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA4C | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by mutect2, varscan2
- SIGLEC10 | c.1415C>G p.P472R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR2 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM11 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- TMTC2 | c.655A>G p.R219G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRANK1 | c.4267G>T p.A1423S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRPM6 | c.117T>A p.C39* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- UBR2 | c.1497G>T p.K499N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2
- UGT3A1 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZC3H7A | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ANK1 | c.3549C>A p.A1183= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- BCL9 | c.3525C>T p.G1175= | Silent (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- LDLR | c.1924T>C p.L642= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- MICAL1 | c.1758G>A p.V586= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SLC7A3 | c.165C>A p.G55= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as rs776093743; called by muse, mutect2, varscan2
- TGFBR2 | c.138G>A p.K46= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ELMOD1 | c.-86+433T>C | Intron (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- FAM135A | c.823+4089A>G | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as rs1339667349, COSV99526897; called by muse, mutect2, varscan2
- IGHG1 | chr14:105737800 T>C | 3'Flank (SNP) | VAF 3/49 reads (6%) | catalogued as rs587721044; called by muse, mutect2
- POLA1 | c.2947-20859C>T | Intron (SNP) | VAF 14/16 reads (88%) | catalogued as rs377097365; called by muse, mutect2, varscan2
- PSAP | c.-2C>G | 5'UTR (SNP) | VAF 17/76 reads (22%) | catalogued as rs761008771, COSV67550056; called by muse, mutect2, varscan2
